Gene-level copy-number profile of tumor specimen TCGA-36-2532-01A from TCGA case TCGA-36-2532, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.1 years (22,333 days).
Specimen TCGA-36-2532-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e610d760-7a91-41f9-aac6-4981ce6e54eb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-2532-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a6e266c8-e1b8-46c6-808f-47b4082baf45

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 68; copy number 2: 12,273; copy number 3: 441; copy number 4: 41,625; copy number 5: 151; copy number 6: 4,756; copy number 7: 162; copy number 8: 263; copy number 9: 9; copy number 10: 59; copy number 14: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-36-2532-01A-01D-1043-01): tumor purity 0.86, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 73 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:70,125,070–70,126,609, 1 gene, copy number 9: AC139700.1.
- chr3:122,660,613–123,225,227, 8 genes, copy number 9 (within-gene range 6–9): EIF4BP8, PARP14, HSPBAP1, SLC49A4, LINC02035, SEMA5B, PDIA5, MIR7110.
- chr3:168,858,659–169,038,416, 5 genes, copy number 14: RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr6:22,569,566–22,675,493, 3 genes, copy number 10: HDGFL1, AL033539.1, AL033539.2.
- chr10:79,068,966–80,437,115, 56 genes, copy number 10 (within-gene range 8–10): ZMIZ1, PPIF, ZCCHC24, AL133481.1, TPRX1P1, AL133481.3, AL133481.2, EIF5AL1, BX248123.1, RPS12P18, SFTPA2, MBL3P, SFTPA3P, SFTPA1, LINC02679, AL132656.2, NUTM2B-AS1, AL132656.3, AL132656.4, BEND3P3, AL132656.1, NUTM2B, AL135925.1, NUTM2E, NPAP1P2, CTSLP6, PGGT1BP2, AL512662.1, BMS1P21, MBL1P, SFTPD, SFTPD-AS1, ZNRF2P3, DPY19L2P5, AL356095.1, C1DP3, C1DP2, C1DP4, TMEM254-AS1, AL356095.3, TMEM254, AL356095.2, RPL22P18, PLAC9, ANXA11, LINC00857, RPS12P2, AL513174.1, EIF5AP4, AL359195.2, MAT1A, ZNF519P1, AL359195.1, DYDC1, DYDC2, PRXL2A.

Autosomal genes at a single copy (total copy number 1): 68. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
